Somatic mutation profile of tumor specimen 0DE0T4 from CCDI case PBBKSS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 19.6 years (7,163 days).
Specimen 0DE0T4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 215d6fe0-85cd-4ac2-9113-180655a954f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE0QR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8feb82b2-3ce0-467d-ad38-28167c1fdbb4

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL7A | c.574G>A p.V192M (on ENST00000261822 / NM_001024808.3; = p.V213M on NM_020993.5) | Missense Mutation (SNP) | VAF 121/619 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs949794860, COSV99947042; called by muse, mutect2, varscan2
- SULT1A1 | c.373-70C>T | Intron (SNP) | VAF 17/185 reads (9%) | called by muse, mutect2, varscan2
